Clinical report (de-identified scan), EXCEPTIONAL_RESPONDERS case ER-ACGR, project EXCEPTIONAL_RESPONDERS-ER (Exceptional Responders), specimen ER-ACGR-TTP1-A (Primary Tumor).

[page 1 of 9]
RUN DATE: [REDACTED] +1774 [REDACTED] Specimen Inquiry
RUN TIME: [REDACTED]

PATIENT: [REDACTED] ACCT #: [REDACTED] LOC: [REDACTED] U #: [REDACTED]
REG DR: [REDACTED] AGE/SX: [REDACTED] ROOM: [REDACTED] REG: [REDACTED]
DOB: [REDACTED] BED: [REDACTED] DIS: [REDACTED]
STATUS: [REDACTED] TLOC: [REDACTED]

-1
+0

SPEC #: [REDACTED] RECD: [REDACTED] +0 STATUS: [REDACTED] REQ #: [REDACTED]
COLL: [REDACTED] +0 SUBM DR: [REDACTED] MD
ENTERED: [REDACTED] +0 SP TYPE: SURGICAL OTHR DR: [REDACTED]
ORDERED: LEVEL IV TISSUE, IMMUNOPEROX/7

FINAL DIAGNOSIS

RIGHT LUNG MASS, CORE BIOPSY: POORLY DIFFERENTIATED ADENOCARCINOMA WITH EXTENSIVE NECROSIS INVOLVING LUNG PARENCHYMA.

IMMUNOHISTOCHEMICAL STAINS FOR CK7 AND TTF-1 ARE POSITIVE.

IMMUNOHISTOCHEMICAL STAINS FOR CK20, CK5/6, P63, CHROMOGRANIN AND SYNAPTOPHYSIN ARE NEGATIVE. (SEE COMMENT)

Additional Notes/Comments:

The submitted core biopsy show a very poorly differentiated tumor composed of sheets of malignant cells with enlarged irregular nuclei and no evidence of definitive differentiation. The above immunohistochemical profile is consistent with an adenocarcinoma lung primary.

This test was developed and its performance characteristics determined by [REDACTED]. It has not been cleared or approved by the US FDA. The FDA has determined that such approval is not necessary. Appropriate positive controls were stained alongside sections from this case. The control tissue was examined and judged to be technically acceptable.

This represents the diagnosis and comment fields only.
For the complete pathology report, see patient chart.
Dictated and signed out by [REDACTED]

[page 2 of 9]
MAIN

Name: [REDACTED]
Phys: [REDACTED]
DOB: [REDACTED] Sex: F
Acct: [REDACTED] UNK
Exam Date: [REDACTED] +0
Radiology No [REDACTED]
Unit No: [REDACTED]

EXAMS: [REDACTED] CT CHEST WITH CONTRAST Reason for Exam:: R LUNG MASS

CT SCAN OF THE CHEST ABDOMEN AND PELVIS

INDICATION: R LUNG MASS, BRAIN MASS HOSPD.

COMPARISON: Previous chest x-ray.

TECHNIQUE: Intravenous and oral contrast.

FINDINGS:

Postsurgical changes present in the right neck from the earlier VAD placement. There is a 13 millimeter and two 6-mm lymph nodes in the precarinal region with a 13 mm lymph node anterior to the right mainstem bronchus and a 10 mm lymph node anterior to left mainstem bronchus. There is no evidence for left hilar adenopathy. A subcarinal mass is present extending caudal and laterally measuring 3.2 x 1.9 cm consistent with a lymph node. A 3.8 x 2.4 cm caudal right hilar lymph node along with a lateral 2.7 x 1.4 cm lymph node are observed. The right hilum becomes confluent with a large right lower lobe mass measuring 7.9 by 6.9 x 7.7 cm in size. Caudal and lateral to the large mass is a 12 mm lung nodule suspicious for a metastasis. The interstitial markings are course and about the mass which could represent lymphangitic invasion. There is no evidence for left-sided nodules. There is no evidence for significant axillary adenopathy. The lymph nodes and the large mass have low-attenuation centrally suspicious for necrosis. Compressive atelectasis is noted about the large mass. Mild to moderate emphysematous change is present bilaterally. There is an ovoid mass within the deep central aspect of the right breast measuring 1.6 x 1.1 cm. This well-circumscribed and may be unrelated to the lung masses. This has indolent characteristics and could represent a fibroadenoma. If indicated a mammogram and ultrasound could be obtained.

Within liver segment 7 is a 3.0 x 3.5 cm mass suspicious for a metastasis. No other liver masses are present. The left adrenal gland is slightly nodular without evidence for a definable mass. The right adrenal gland is within normal limits. The appendix is air-filled and within normal limits. There is no evidence for retroperitoneal adenopathy. The other abdominal and pelvic viscera are unremarkable. Small follicles are present within both ovaries. The osseous structures are unremarkable.

IMPRESSION:

[page 3 of 9]
Name

Phys

DOB:

Acct

Exam Date:

Radiology No:

Unit No:

Sex: F

+0

EXAMS:

CT CHEST WITH CONTRAST

Reason for Exam::

R LUNG MASS

<Continued>

1. Findings consistent with right lower lobe lung carcinoma with right hilar and mediastinal adenopathy.
2. Probable liver metastasis.
3. Right breast mass which may be unrelated to the lung findings.

[page 4 of 9]
Name: [REDACTED]
Phys: [REDACTED]
DOB: [REDACTED] Sex: F
Acct: [REDACTED]
Exam Date: [REDACTED] +921
Radiology N [REDACTED]
Unit No: [REDACTED]

EXAMS:

CT CHEST NO CONTRAST	Reason for Exam::
CT ABDOMEN W-O CONTRAST	LUNG CANCER RESTAGING
	LUNG CANCER RESTAGING

Technique: Axial CT of the chest and abdomen following oral but no IV contrast with sagittal and coronal multiplanar reformatting.

COMPARISON: [REDACTED] ~+787

CT CHEST:

The lungs are free of consolidation. No worrisome pulmonary nodule or mass is present. No pleural or pericardial effusion is seen and there is no lymphadenopathy. Evaluation for smaller mediastinal lymph nodes is of somewhat lowered sensitivity compared to prior study due to lack of IV contrast. There are relatively numerous but predominately subcentimeter and 1 cm AP window, precarinal and subcarinal lymph nodes which appear stable accounting for differences in technique. The ascending and descending thoracic aortic caliber is within normal limits. A right jugular venous access device is present with catheter tip in the SVC. There are apical predominant moderately severe emphysematous changes. Right lower lobe cavitary mass is again seen without significant interval change measure approximately 3 cm transversely.

CT ABDOMEN:

Evaluation of the solid viscera is of lowered sensitivity due to lack of IV contrast. There is continued mild left adrenal thickening. Mild sclerosis is again present along with bilateral mild perinephric stranding. The other solid viscera have an unremarkable appearance. There is no evidence of intestinal obstruction, biliary dilatation, or ascites. Evaluation for small mesenteric and retroperitoneal lymph nodes is challenging due to lack of IV contrast. There are numerous subcentimeter and approximately 1 cm aortocaval and left para-aortic retroperitoneal lymph nodes which appear stable. The stomach again appears somewhat thick-walled although partially contracted state precludes accurate assessment of wall thickness.

The gallbladder appears normal.

within normal limits. There is mild to moderate aortoiliac atherosclerotic calcification.

CT PELVIS:

Not scan due to referring provider's request.

[page 5 of 9]
Name: [REDACTED]
Phys: [REDACTED]
DOB: [REDACTED] Sex: F
Acct: [REDACTED]
Exam Date: [REDACTED] Status: [REDACTED] +921
Radiology: [REDACTED]
Unit No: [REDACTED]

EXAMS:

[REDACTED] CT CHEST NO CONTRAST Reason for Exam::
[REDACTED] CT ABDOMEN W-O CONTRAST LUNG CANCER RESTAGING
LUNG CANCER RESTAGING

<Continued>

Bone windows: No acute osseous abnormality or suspicious lytic/blastic lesion identified.

IMPRESSION:

1. Stable appearance of the chest and abdomen compared with [REDACTED]
2. Unchanged subcentimeter and 1 cm mediastinal and retroperitoneal lymph nodes as described.
3. Stable right lower lobe cavitory lesion.
4. Right jugular VAD in appropriate position.
5. No new findings suspicious for metastatic disease identified.
- Lowered sensitivity examination due to lack of IV contrast which would be generally recommended for cancer restaging, and could be performed in conjunction with dialysis if needed.
6. Continued apparent gastric wall thickening as described. Stable left adrenal thickening.
7. Emphysema.

[REDACTED]

[REDACTED]

[page 6 of 9]
Phys: [REDACTED]
DOB: [REDACTED]
Acct: [REDACTED]
Exam Date: [REDACTED] Status: [REDACTED] +1586
Radiology No: [REDACTED]
Unit No: [REDACTED]

Sex: F

EXAMS:

CT CHEST WITH CONTRAST

Reason for Exam::

LUNG CANCER WITH BRAIN MET

CT CHEST

INDICATION: Lung cancer, brain metastases

TECHNIQUE: Axial chest CT with IV contrast and with sagittal and coronal multiplanar reformatting.

COMPARISON: [REDACTED] +1397

FINDINGS:

Lymph Nodes: No significant axillary adenopathy is demonstrated. There continues to be pretracheal lymph nodes that are enlarged but stable when compared with previous.

Mediastinum: No evidence for a mediastinal mass or cyst. A right IJ venous access device remains in place with its tip in the SVC unchanged. There continues to be enlargement of right hilar lymph node similar to previous, measuring approximately 2 x 1.5 cm. Again noted is a 1.8 centimeter nodule in the inferior aspect of the right breast, stable.

Pulmonary Parenchyma: Bullous emphysema is present particularly in the upper lobes. There is a spiculated mass that extends to the posterior pleura in the right upper lobe that has increased slightly in size from previous. Today this mass measures 9 mm in maximal dimension. Previously it measured 7 mm. The size and appearance of the cavitary mass in the right lower lobe is unchanged. Scarring or fibrosis is again seen at the left lung base laterally.

Cardiovascular: No pericardial effusion. Calcification is present in the thoracic aorta but there's no aneurysm. Great vessel origins appear normal.

Osseous structures: No lytic or blastic changes.

Upper abdomen: Liver, spleen and adrenal glands are unremarkable. There is minimal streaking of the upper pole the left kidney perinephric fat and prominence of calyces but this structure is incompletely evaluated on this study. The appearance is unchanged from previous. Mild thickening of the left adrenal gland is unchanged.

[page 7 of 9]
Name: [REDACTED]
Phys: [REDACTED]
DOB: [REDACTED] Sex: F
Acct: [REDACTED] UNK
Exam Date: [REDACTED] Status: [REDACTED] +1586
Radiology No: [REDACTED]
Unit No: [REDACTED]

EXAMS: [REDACTED] CT CHEST WITH CONTRAST Reason for Exam::
[REDACTED] LUNG CANCER WITH BRAIN MET
<Continued>

IMPRESSION:
No evidence for disease progression. No new lesions or nodes. Slight
increase in size of the spiculated density right upper lobe which
could be related to volume averaging.

Stable right breast nodule, unchanged.

[page 8 of 9]
Name: [REDACTED]
Phys: [REDACTED]
DOB: [REDACTED] Sex: [REDACTED]
Acct: [REDACTED]
Exam Date: [REDACTED] Status: [REDACTED] +75
Radiology No: ([REDACTED])
Unit No: [REDACTED]

EXAMS:

[REDACTED] CT CHEST WITH CONTRAST

Reason for Exam::
LUNG CANCER-RESTAGING,? [REDACTED]

CT SCAN OF THE CHEST AND ABDOMEN

INDICATION: LUNG CANCER-RESTAGING,? LOCULATED EFFUSION/ABSCCESS LUNG,
RESTAGING LUNG CANCER/ABSEST OF LUNG.

COMPARISON: Prior studies, most recently dated [REDACTED]. +46

TECHNIQUE: With intravenous and oral contrast.

FINDINGS:

The enlarged mediastinal lymph nodes remain unchanged with the largest measuring 16 mm. The low attenuating right hilar mass now measures 2.4 x 1.9 cm when previously it measured 2.9 x 2.0 cm. The right hilar lymph node in the caudal aspect now measures 13 mm when previously it measured 15 mm. The present noted large fluid-filled cavity posteriorly at the right lung base now measures 6.0 x 5.6 cm when previously it measured 9.6 x 9.0 cm. The amount of fluid is markedly reduced and air is present in this region. A small amount of pleural fluid is present along the caudal and a lateral wall which appears loculated. Emphysematous change is again noted in the upper lung zones. There is no evidence for a lung nodule.

The low-attenuation mass in segment 7 near the dome of the liver now measures 2.2 x 2.1 cm when previously it measured 2.9 x 2.8 cm. This is now more low attenuating centrally, suspicious for necrosis, and the edges are less enhancing. The findings consistent a small cyst just cephalad to this region remains unchanged. No other liver masses are present. There is no evidence for retroperitoneal adenopathy. The other abdominal viscera are unremarkable. The osseous structures are unremarkable.

IMPRESSION:

1. Decrease in size of the right hilar mass, lung collection and liver mass.
2. Small loculated right pleural effusion.

[page 9 of 9]
[REDACTED]

Name: [REDACTED]
Phys: [REDACTED]
DOB: [REDACTED] Age: [REDACTED] S
Acct: [REDACTED] Loc: UNK
Exam Date: [REDACTED]
Radiology No: [REDACTED]
Unit No: [REDACTED]

EXAMS:

[REDACTED] CT CHEST WITH CONTRAST
<Continued>

Reason for Exam::
LUNG CANCER-RESTAGING, ? [REDACTED]

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file c80f8f58-baa4-4b65-80b9-c698c6a99983 (ER0226 ER-ACGR Clinical Report_Redacted_Sanitized.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).